Somatic mutation profile of tumor specimen MP2PRT-PATEXZ-TMP1-A (aliquot MP2PRT-PATEXZ-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATEXZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,989 days).
Specimen MP2PRT-PATEXZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f37c1f7d-0c45-4c8e-a0c3-545787ed911b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATEXZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATEXZ-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe20eaf2-03c4-497f-810a-ab1129fc1284

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, In Frame Ins 2, Nonsense Mutation 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF3 | c.1103C>T p.A368V (on ENST00000311519 / NM_001145168.1; = p.A169V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/373 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs148181027; called by muse, mutect2, varscan2
- C1orf115 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 135/326 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs753438102, COSV54274592; called by muse, mutect2, varscan2
- CDH19 | c.1918C>G p.Q640E | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV50954246; called by muse, mutect2, varscan2
- CTCFL | c.887C>T p.T296M | Missense Mutation (SNP) | VAF 148/369 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1377403378, COSV54776340; called by muse, mutect2, varscan2
- DMD | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 76/335 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1169160513; called by muse, mutect2, varscan2
- IFI16 | c.901A>G p.T301A | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs1010277237; called by muse, mutect2, varscan2
- KLHL4 | c.1244T>C p.M415T | Missense Mutation (SNP) | VAF 210/440 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs1290137094; called by muse, mutect2, varscan2
- OGFRL1 | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 42/352 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.078); catalogued as rs1174728040, COSV100965761, COSV64971795; called by muse, mutect2, varscan2
- TRIM51 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as rs528409876; called by muse, mutect2
- TRPM8 | c.3049G>A p.V1017I | Missense Mutation (SNP) | VAF 83/454 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs897159839, COSV61225258; called by muse, varscan2
- USH2A | c.141G>C p.K47N | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV56429750; called by muse, mutect2
- CYP2W1 | c.1067_1068insCC p.F357Rfs*30 | Frame Shift Ins (INS) | VAF 242/618 reads (39%) | called by mutect2, varscan2
- IGKV3D-15 | chr2:90115400 ins CCCCC | In Frame Ins (INS) | VAF 18/32 reads (56%) | called by mutect2, varscan2
- KIF13B | c.3759_3760insCCCAGG p.V1253_T1254insPR | In Frame Ins (INS) | VAF 49/390 reads (13%) | called by mutect2, varscan2
- KIF13B | c.3758T>G p.V1253G | Missense Mutation (SNP) | VAF 55/398 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by mutect2, varscan2
- MLLT6 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 16/600 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PLEKHG4 | c.1668G>C p.E556D | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2
- SLIT3 | c.104C>G p.P35R | Missense Mutation (SNP) | VAF 23/897 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TPM3 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 16/390 reads (4%) | called by muse, mutect2
- EXPH5 | c.3474G>A p.E1158= | Silent (SNP) | VAF 19/447 reads (4%) | called by muse, mutect2
- FSIP2 | c.1230C>T p.F410= | Silent (SNP) | VAF 34/195 reads (17%) | catalogued as rs549124494; called by muse, mutect2, varscan2
- KLF18 | c.57C>G p.L19= | Silent (SNP) | VAF 15/474 reads (3%) | called by muse, mutect2
- LAX1 | c.522C>T p.I174= | Silent (SNP) | VAF 14/414 reads (3%) | called by muse, mutect2
- PCDHGB5 | c.576G>A p.P192= | Silent (SNP) | VAF 162/384 reads (42%) | catalogued as COSV54036190; called by muse, mutect2, varscan2
- TRIL | c.255C>G p.L85= | Silent (SNP) | VAF 81/408 reads (20%) | called by muse, mutect2, varscan2
- WNT1 | c.267C>G p.A89= | Silent (SNP) | VAF 30/678 reads (4%) | catalogued as rs369711501; called by muse, mutect2
- ZNFX1 | c.4065C>T p.C1355= | Silent (SNP) | VAF 54/400 reads (14%) | catalogued as rs547994891; called by muse, varscan2
- ABLIM3 | c.*1170G>C | 3'UTR (SNP) | VAF 13/439 reads (3%) | called by muse, mutect2
